PECGS case C083-000058 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum.
https://portal.gdc.cancer.gov/cases/09142926-e970-41f3-af3a-989ea4cf84cb

Demographics
Sex at birth: male; Age at index: 57 years; Year of birth: 1964; Education level: High School Graduate or GED.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Rectum, NOS; Age at diagnosis: 56.9 years (20,783 days); AJCC clinical stage: Stage IVA; AJCC pathologic stage: Stage IVA; Progression or recurrence: no.

Other clinical attributes
- BMI: 17.18.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 2.25; Alcohol history: No.

Biospecimens (2 samples)
- Sample C083-000058_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000058_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
